Gene-level copy-number profile of tumor specimen TCGA-DD-AADF-01A from TCGA case TCGA-DD-AADF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 64.7 years (23,614 days).
Specimen TCGA-DD-AADF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.ed2f6a4d-875c-45e1-add1-92c088f4b6d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/937f41e3-dd94-4e89-ac44-8899fb4bcc12

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 674; copy number 2: 9,746; copy number 3: 34,603; copy number 4: 7,673; copy number 5: 2,361; copy number 6: 1,363; copy number 7: 2,607; copy number 8: 175; copy number 9: 470; copy number 10: 144.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADF-01A-11D-A40Q-01): tumor purity 0.9, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,396 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–193,091,777, 1,400 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:193,473,224–200,214,322, 66 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:26,764,284–27,523,684, 45 genes, copy number 7: SLC35F6, CENPA, CDKN2AIPNLP2, DPYSL5, AC013472.1, MAPRE3, MAPRE3-AS1, TMEM214, AGBL5, AGBL5-AS1, AC013472.2, AGBL5-IT1, AC013403.2, OST4, EMILIN1, KHK, CGREF1, ABHD1, PREB, PRR30, TCF23, AC013403.1, SLC5A6, ATRAID, CAD, SLC30A3, DNAJC5G, TRIM54, UCN, MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR.
- chr5:1,173,141–1,295,068, 5 genes, copy number 10 (within-gene range 6–10): CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:34,651,457–34,651,888, 1 gene, copy number 8: AC025754.2.
- chr5:134,436,711–134,583,230, 6 genes, copy number 10 (within-gene range 5–10): AC005355.1, RNU6-456P, LINC01843, RN7SL541P, AC005355.2, JADE2.
- chr5:143,489,855–143,531,350, 1 gene, copy number 9: AC016598.1.
- chr5:157,731,420–158,278,813, 16 genes, copy number 7: THG1L, LSM11, AC026407.1, CLINT1, RNU6-260P, AC008677.2, RNU2-48P, MARK2P11, AC008677.1, AC008677.3, AC025437.5, AC025437.4, AC025437.6, AC025437.3, AC025437.2, AC025437.1.
- chr5:172,690,454–172,785,424, 7 genes, copy number 8: AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4.
- chr13:18,467,172–32,315,363, 320 genes, copy number 7 (broad region; genes not listed).
- chr13:50,082,169–50,906,856, 1 gene, copy number 7 (within-gene range 1–7): DLEU1.
- chr13:50,519,364–101,720,856, 550 genes, copy number 7 (broad region; genes not listed).
- chr13:101,717,564–101,967,746, 4 genes, copy number 7: AL160153.1, RNU1-24P, HMGB3P7, MIR2681.
- chr13:106,232,131–114,337,626, 151 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr16:50,548,396–51,442,519, 28 genes, copy number 8 (within-gene range 3–8): NKD1, AC007608.2, AC007608.4, AC007608.1, AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1.
- chr17:58,982,638–83,095,122, 794 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr20:50,429,190–50,429,483, 1 gene, copy number 8: RN7SL636P.

Autosomal genes at a single copy (total copy number 1): 674. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
